Somatic mutation profile of tumor specimen TCGA-AX-A3FT-01A (aliquot TCGA-AX-A3FT-01A-11D-A228-09) from TCGA case TCGA-AX-A3FT, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 64.5 years (23,543 days).
Specimen TCGA-AX-A3FT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1189e3e2-1944-4f26-b711-5f4ff707c874.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A3FT-10A (Blood Derived Normal), aliquot TCGA-AX-A3FT-10A-01D-A22A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a0890e7-f868-4182-8908-f531a4baac16

The open-access MAF lists 1,538 somatic variants for this specimen: 1,169 protein-altering or splice-affecting, 336 silent, 33 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 831, Silent 336, Frame Shift Del 208, Nonsense Mutation 44, Frame Shift Ins 42, Splice Site 21, Intron 16, Splice Region 12, In Frame Del 10, 3'UTR 7, RNA 4, 3'Flank 3.

Variants (750 of 1,538; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.5012del p.N1671Ifs*4 (on ENST00000272895 / NM_173076.3; = p.N1353Ifs*4 on NM_015657.3) | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | catalogued as rs387906285, CD051281; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BRCA1 | c.329dup p.E111Gfs*3 | Frame Shift Ins (INS) | VAF 12/77 reads (16%) | catalogued as rs80357604; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DOCK6 | c.1362_1365del p.T455Sfs*24 | Frame Shift Del (DEL) | VAF 21/101 reads (21%) | catalogued as rs730882238; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ERBB2 | c.2524G>A p.V842I | Missense Mutation (SNP) | VAF 9/24 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1057519738, COSV104371920, COSV54062791; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ERBB3 | c.655T>C p.F219L | Missense Mutation (SNP) | VAF 16/55 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); catalogued as COSV57246260, COSV99918190; called by muse, mutect2, varscan2
- KMT2B | c.521del p.P174Qfs*20 | Frame Shift Del (DEL) | VAF 14/66 reads (21%) | catalogued as rs763183959; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NCSTN | c.17del p.G6Vfs*22 | Frame Shift Del (DEL) | VAF 16/93 reads (17%) | catalogued as rs1266104510; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NF1 | c.233del p.N78Ifs*7 | Frame Shift Del (DEL) | VAF 8/23 reads (35%) | catalogued as rs1438566555; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- OFD1 | c.710del p.K237Sfs*6 | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | catalogued as rs312262845; ClinVar: pathogenic; called by mutect2, varscan2
- PCDH19 | c.1091del p.P364Rfs*4 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | catalogued as rs758946412, CD134966; ClinVar: pathogenic; called by mutect2, pindel
- PIK3R2 | c.1117G>A p.G373R | Missense Mutation (SNP) | VAF 16/37 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587776934, CM126686, COSV55846573; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RECQL | c.120del p.V41Sfs*2 | Frame Shift Del (DEL) | VAF 10/58 reads (17%) | catalogued as rs745659712, COSV59084411; ClinVar: pathogenic; called by mutect2, varscan2
- RPE65 | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs61752871, CM983758; ClinVar: pathogenic; called by muse, varscan2
- TP63 | c.1927C>T p.R643* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as rs1560311554, COSV53199004; ClinVar: likely pathogenic; called by mutect2, varscan2
- WRN | c.3382del p.S1128Vfs*34 | Frame Shift Del (DEL) | VAF 44/109 reads (40%) | catalogued as rs778872619; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- A2M | c.3643G>A p.A1215T | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.489); catalogued as rs1294347145, COSV59385517; called by muse, mutect2, varscan2
- AARD | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375266231, COSV65599577, COSV65600510; called by muse, mutect2, varscan2
- ABCA2 | c.5566C>T p.Q1856* (on ENST00000614293; = p.Q1826* on NM_001606.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 7/42 reads (17%) | catalogued as COSV99688690; called by muse, mutect2, varscan2
- ABCA7 | c.1489C>T p.R497C | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99566871; called by muse, mutect2, varscan2
- ABCA8 | c.4028A>G p.Y1343C | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99287269; called by muse, mutect2
- ABCB6 | c.1579G>A p.V527I | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.391); catalogued as COSV54698876, COSV99202531; called by muse, mutect2, varscan2
- ABCC1 | c.62C>T p.T21M | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs762542019, COSV100580598; called by muse, mutect2, varscan2
- ABCC4 | c.3655del p.I1219Sfs*11 | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | catalogued as rs756859429, COSV65316407; called by mutect2, varscan2
- ABCC6 | c.1576C>T p.R526W | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs773079563, COSV52741597; called by muse, mutect2, varscan2
- ABCC6 | c.123del p.M42Cfs*39 | Frame Shift Del (DEL) | VAF 23/73 reads (32%) | catalogued as rs746531177; called by mutect2, varscan2
- ABCG5 | c.227T>C p.V76A | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV99575736; called by muse, mutect2, varscan2
- ABHD17A | c.708-1G>A p.X236_splice (on ENST00000292577 / NM_001130111.2; = p.X287_splice on NM_031213.4) | Splice Site (SNP) | VAF 12/37 reads (32%) | catalogued as rs1292168215, COSV99171432; called by muse, mutect2, varscan2
- ABHD17C | c.367A>C p.M123L | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV99358881; called by muse, mutect2
- ABI3 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as rs200803220, COSV56799265; called by muse, mutect2, varscan2
- ABL2 | c.2764G>A p.V922I (on ENST00000502732 / NM_007314.4; = p.V907I on NM_005158.5) | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs750153761, COSV100772276; called by muse, mutect2, varscan2
- ABR | c.1807G>A p.V603M (on ENST00000302538 / NM_021962.5; = p.V566M on NM_001092.5) | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as rs759310881, COSV99348873; called by muse, mutect2, varscan2
- ABRAXAS1 | c.615_617del p.E205del | In Frame Del (DEL) | VAF 9/47 reads (19%) | catalogued as rs759905964; called by pindel, varscan2
- AC008397.2 | c.1466G>A p.R489H | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1264438482, COSV53208745; called by muse, mutect2, varscan2
- AC008676.3 | c.635del p.G212Vfs*24 | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | catalogued as rs748255153; called by mutect2, pindel, varscan2
- ACACB | c.4192del p.L1398Sfs*26 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | catalogued as rs1565953344, COSV58128358; called by mutect2, pindel, varscan2
- ACOT4 | c.548T>C p.F183S | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100412967; called by muse, mutect2, varscan2
- ACSM2A | c.918G>T p.K306N (on ENST00000219054; = p.K227N on NM_001308169.2) | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99525854; called by muse, mutect2, varscan2
- ACTN1 | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751173836, COSV51998373; called by muse, mutect2, varscan2
- ACTN3 | c.2645C>T p.P882L | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.021); catalogued as rs748740930, COSV100074563; called by muse, mutect2, varscan2
- ACTN4 | c.733G>T p.D245Y | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99400734; called by muse, mutect2, varscan2
- ACTR5 | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754719622, COSV54760806; called by muse, mutect2, varscan2
- ACTR5 | c.1358A>T p.E453V | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99710338; called by muse, mutect2, varscan2
- ADAM11 | c.104dup p.P37Tfs*10 | Frame Shift Ins (INS) | VAF 11/46 reads (24%) | catalogued as rs767694891; called by mutect2, varscan2
- ADAM11 | c.1927G>A p.G643S | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.962); catalogued as rs202023224, COSV99567966; called by muse, mutect2, varscan2
- ADAM7 | c.2050G>A p.G684R | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as rs200101638, COSV51548017; called by muse, mutect2
- ADAMTS15 | c.154G>A p.G52R | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs1356595320, COSV100143923; called by muse, mutect2, varscan2
- ADAMTS2 | c.400G>A p.G134R | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.798); catalogued as COSV51080291; called by muse, mutect2, varscan2
- ADAMTS3 | c.2503A>G p.N835D | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.58); PolyPhen benign (0.027); catalogued as COSV99712443; called by muse, mutect2, varscan2
- ADAMTSL5 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780150402, COSV100389287; called by muse, mutect2, varscan2
- ADGRA1 | c.1280C>A p.P427H | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.629); catalogued as COSV100811049; called by muse, mutect2, varscan2
- ADNP | c.3047del p.K1016Rfs*11 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | catalogued as rs761350619; called by mutect2, varscan2
- ADRA1A | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as rs765619798, COSV52363407; called by muse, mutect2, varscan2
- AFAP1L1 | c.1975G>T p.G659* | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | catalogued as COSV99696231; called by muse, mutect2, varscan2
- AGAP6 | c.1006A>G p.K336E (on ENST00000374056 / NM_001365867.1; = p.K359E on NM_001077665.2) | Missense Mutation (SNP) | VAF 55/266 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.714); catalogued as COSV100929191; called by muse, mutect2, varscan2
- AGAP6 | c.1480C>T p.R494* (on ENST00000374056 / NM_001365867.1; = p.R517* on NM_001077665.2) | Nonsense Mutation (SNP) | VAF 80/236 reads (34%) | catalogued as rs782767193, COSV65017686; called by muse, mutect2, varscan2
- AGPAT3 | c.571G>A p.V191M | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV99377944; called by muse, mutect2, varscan2
- AHCTF1 | c.3569C>T p.S1190L (on ENST00000366508; = p.S1164L on NM_015446.5) | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs377375258; called by muse, mutect2, varscan2
- AHNAK2 | c.9293C>T p.T3098M | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.062); catalogued as rs374657511, COSV60907227; called by muse, mutect2, varscan2
- AK3 | c.571G>A p.G191R | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100729470, COSV63346252; called by muse, mutect2, varscan2
- AKAP12 | c.1021G>A p.G341R | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.161); catalogued as rs561110627, COSV53579815, COSV99484575; called by muse, mutect2, varscan2
- AKT3 | c.850C>A p.H284N | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99797450; called by muse, mutect2, varscan2
- ALDH1A3 | c.849del p.K284Rfs*83 | Frame Shift Del (DEL) | VAF 15/59 reads (25%) | catalogued as rs758955164; called by mutect2, pindel, varscan2
- ALDH1L1 | c.1778C>T p.T593I | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99857723; called by muse, mutect2, varscan2
- ALDH8A1 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750250670, COSV99665103; called by mutect2, varscan2
- ALDOA | c.728C>A p.P243H (on ENST00000642816 / NM_001243177.4; = p.P189H on NM_184041.5) | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100582304; called by muse, mutect2, varscan2
- ALG2 | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs376229898, COSV53059281; called by muse, mutect2, varscan2
- ALS2CL | c.1480G>A p.G494S | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs140756490; called by muse, mutect2, varscan2
- ALYREF | c.726G>T p.K242N | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV100485920; called by muse, mutect2, varscan2
- ANGEL2 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.007); catalogued as COSV64738660; called by muse, mutect2, varscan2
- ANK1 | c.5602T>G p.F1868V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV99227411; called by muse, mutect2
- ANKMY1 | c.2215C>A p.L739M | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); catalogued as COSV99803681; called by mutect2, varscan2
- ANKRD28 | c.1073T>G p.L358R | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101081011, COSV67516896; called by muse, mutect2, varscan2
- ANKS1A | c.3085C>A p.L1029M | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100833000; called by muse, mutect2, varscan2
- ANKS3 | c.617G>T p.R206L | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.313); catalogued as COSV100423372; called by muse, mutect2, varscan2
- ANO9 | c.643G>A p.G215R | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.636); catalogued as rs778954042, COSV100241290; called by muse, mutect2, varscan2
- ANOS1 | c.2003G>A p.R668H | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs775708192, COSV52927509; called by muse, mutect2, varscan2
- AOC1 | c.139T>G p.F47V | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100711085; called by muse, mutect2, varscan2
- AP2A1 | c.2875C>T p.R959C | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1320828048, COSV58242282; called by muse, mutect2, varscan2
- AP2A2 | c.1185G>A p.M395I | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.584); catalogued as rs770771246, COSV100173459; called by muse, mutect2, varscan2
- AP4M1 | c.736C>A p.P246T | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV100385255; called by muse, mutect2, varscan2
- AP5Z1 | c.2242C>T p.R748C | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs754070937, COSV62243015; called by mutect2, varscan2
- APBA2 | c.1130T>C p.L377P | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101258244; called by muse, mutect2, varscan2
- APLP1 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as rs778700083, COSV55706133, COSV99697999; called by muse, mutect2, varscan2
- APOE | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.842); catalogued as rs947015878, COSV99376338; called by muse, mutect2
- ARGLU1 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.122); catalogued as COSV100639800; called by muse, mutect2, varscan2
- ARHGAP22 | c.1679A>G p.D560G | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99986317; called by muse, mutect2, varscan2
- ARHGAP35 | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101351979; called by muse, mutect2, varscan2
- ARHGEF10 | c.3314A>C p.H1105P (on ENST00000398564; = p.H1080P on NM_014629.4) | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100036001; called by muse, mutect2, varscan2
- ARHGEF17 | c.1418C>T p.T473M | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); catalogued as rs1047609049, COSV99735760; called by muse, mutect2, varscan2
- ARHGEF17 | c.2333G>A p.G778D | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.67); catalogued as rs146275379; called by muse, mutect2, varscan2
- ARHGEF25 | c.1541G>A p.S514N | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.71); PolyPhen benign (0.009); catalogued as COSV54089647; called by muse, mutect2, varscan2
- ARHGEF4 | c.1366C>T p.H456Y | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as COSV100388935; called by muse, mutect2, varscan2
- ARID1A | c.3977del p.P1326Rfs*155 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | catalogued as COSV61372705; called by mutect2, pindel
- ARID1B | c.5974del p.V1992Wfs*16 | Frame Shift Del (DEL) | VAF 21/89 reads (24%) | catalogued as rs749055122; called by mutect2, pindel, varscan2
- ARID5B | c.147G>T p.K49N | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV54418646, COSV99688718; called by mutect2, varscan2
- ARL4C | c.323T>C p.L108P | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100327133; called by muse, mutect2, varscan2
- ARV1 | c.518del p.K173Sfs*8 | Frame Shift Del (DEL) | VAF 18/32 reads (56%) | catalogued as rs544784472, COSV59618356; called by mutect2, varscan2
- ASIC3 | c.1360C>A p.L454I | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99877557; called by muse, mutect2, varscan2
- ASMTL | c.732del p.G245Afs*47 | Frame Shift Del (DEL) | VAF 16/134 reads (12%) | catalogued as rs1438753766, COSV67243140; called by mutect2, varscan2
- ASXL1 | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.965); catalogued as rs576523117, COSV100041877, COSV60102883, COSV60108753; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATAD2B | c.920del p.K307Rfs*57 | Frame Shift Del (DEL) | VAF 6/49 reads (12%) | catalogued as rs1558707706; called by mutect2, pindel, varscan2
- ATL3 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV60298469; called by muse, mutect2, varscan2
- ATN1 | c.3272G>A p.R1091Q | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as rs1555144546, COSV99980873; called by muse, mutect2, varscan2
- ATP10D | c.2965C>G p.R989G | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs753524004, COSV99906342; called by muse, mutect2, varscan2
- ATP11A | c.1400G>A p.R467H | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs373245197; called by muse, mutect2, varscan2
- ATP13A2 | c.1243del p.R415Gfs*12 | Frame Shift Del (DEL) | VAF 26/95 reads (27%) | catalogued as rs1297149427; called by mutect2, pindel, varscan2
- ATP13A2 | c.1190G>A p.R397H | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as rs781304413, COSV58701746; called by muse, mutect2, varscan2
- ATP1A1 | c.563G>T p.G188V | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99814896; called by muse, mutect2, varscan2
- ATP2A1 | c.580G>A p.V194I | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs201515814; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP8A1 | c.3455G>T p.R1152I | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100047597, COSV52536052; called by muse, mutect2, varscan2
- ATP9A | c.1330C>T p.L444F | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.74); PolyPhen benign (0.125); catalogued as COSV100125782; called by muse, mutect2, varscan2
- ATXN2 | c.956C>T p.P319L (on ENST00000550104; = p.P159L on NM_002973.4) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs752356805, COSV101112932; called by muse, mutect2, varscan2
- AXIN1 | c.1798G>A p.V600M | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs767450750, COSV51989062; called by muse, mutect2, varscan2
- B4GALT4 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs752478533, COSV100785866; called by muse, mutect2, varscan2
- BAHCC1 | c.7454A>C p.K2485T | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100312184; called by muse, mutect2, varscan2
- BBS12 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs200240034, COSV58561755; called by muse, mutect2, varscan2
- BCAR3 | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as rs371841836; called by muse, mutect2, varscan2
- BCOR | c.4288C>T p.Q1430* (on ENST00000378444 / NM_001123385.2; = p.Q1396* on NM_017745.6) | Nonsense Mutation (SNP) | VAF 18/122 reads (15%) | catalogued as rs1309687666, COSV60699481; called by muse, mutect2, varscan2
- BDNF | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV100152027; called by muse, mutect2, varscan2
- BEND5 | c.874T>C p.Y292H | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.86); catalogued as COSV100884190; called by muse, mutect2, varscan2
- BEX5 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100375104; called by muse, mutect2, varscan2
- BIRC2 | c.163A>G p.T55A | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as rs147638046; called by muse, mutect2, varscan2
- BIRC6 | c.1105T>C p.S369P | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV101429377; called by muse, mutect2
- BIRC6 | c.5801G>A p.R1934H | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs147371379; called by muse, mutect2, varscan2
- BOD1L1 | c.3862A>G p.T1288A | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV99240655; called by muse, mutect2, varscan2
- BOD1L1 | c.2045G>A p.R682H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs1298034837, COSV50006319, COSV50019410; called by muse, mutect2, varscan2
- BRAT1 | c.2092G>A p.V698M | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.06); catalogued as rs781355172, COSV61397170; called by muse, mutect2, varscan2
- BRPF1 | c.2845C>G p.R949G | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.06); catalogued as COSV100121456, COSV57408005, COSV57409371; called by muse, mutect2, varscan2
- BRPF1 | c.3310A>G p.I1104V | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.926); catalogued as COSV100115684; called by muse, mutect2
- BSN | c.9085G>A p.A3029T | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs752852851, COSV99610241; called by muse, mutect2, varscan2
- BTBD9 | c.961G>A p.G321S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs774273427, COSV100023128; called by muse, mutect2, varscan2
- BZW1 | c.434C>T p.S145L | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.173); catalogued as COSV100729895; called by muse, mutect2, varscan2
- C10orf82 | c.559+2T>C p.X187_splice (on ENST00000588184 / NM_001350930.2; = p.*155Rext*12 on NM_144661.4) | Splice Site (SNP) | VAF 7/27 reads (26%) | catalogued as COSV100980183; called by muse, mutect2, varscan2
- C12orf43 | c.584del p.K195Rfs*116 | Frame Shift Del (DEL) | VAF 50/173 reads (29%) | catalogued as rs1475639455; called by mutect2, pindel, varscan2
- C1orf112 | c.1816A>G p.S606G | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV99610317; called by muse, mutect2, varscan2
- C1orf162 | c.230del p.P77Qfs*5 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | catalogued as COSV100636254; called by mutect2, pindel, varscan2
- C3orf38 | c.97G>A p.V33I | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as COSV100007520; called by muse, mutect2, varscan2
- C7orf57 | c.506del p.K169Sfs*2 | Frame Shift Del (DEL) | VAF 15/43 reads (35%) | catalogued as rs747591930; called by mutect2, varscan2
- CABP2 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1377696729, COSV99590984; called by muse, mutect2, varscan2
- CACNA1E | c.4781G>A p.R1594H | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1436277931, COSV62382452; called by muse, mutect2, varscan2
- CACNA1G | c.2519G>A p.R840H | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756391037, COSV100662820; called by muse, mutect2, varscan2
- CAMKK1 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV99340693; called by muse, mutect2, varscan2
- CAMSAP1 | c.1396del p.T466Pfs*46 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | catalogued as rs201838505; called by mutect2, varscan2
- CAND2 | c.1463A>G p.D488G (on ENST00000456430 / NM_001162499.2; = p.D395G on NM_012298.3) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV99930037; called by muse, mutect2
- CAPN15 | c.181A>G p.K61E | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.033); catalogued as COSV99562917; called by muse, mutect2, varscan2
- CATSPERD | c.2275G>A p.A759T | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV100486992; called by muse, mutect2, varscan2
- CAV2 | c.188C>T p.T63M | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as rs1355914850, COSV99760881; called by muse, mutect2, varscan2
- CBX7 | c.473C>A p.P158H | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); catalogued as COSV99334259; called by muse, mutect2, varscan2
- CCDC110 | c.833A>T p.N278I | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as COSV100294233; called by muse, mutect2, varscan2
- CCDC120 | c.32C>A p.P11H | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV100900747; called by muse, mutect2, varscan2
- CCDC153 | c.599del p.P200Lfs*4 | Frame Shift Del (DEL) | VAF 8/41 reads (20%) | catalogued as rs745729530; called by mutect2, pindel, varscan2
- CCDC158 | c.1887C>A p.D629E | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.069); catalogued as COSV101187439; called by muse, mutect2, varscan2
- CCDC174 | c.826G>T p.D276Y | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100358762; called by muse, mutect2
- CCDC27 | c.1714C>T p.R572C | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs746602099, COSV53898512; called by muse, mutect2, varscan2
- CCDC30 | c.925C>T p.R309* (on ENST00000340612; = p.R266* on NM_001080850.3) | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as rs149194384, COSV59605343; called by muse, mutect2, varscan2
- CCDC42 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs776086783, COSV99549883; called by muse, mutect2, varscan2
- CCDC57 | c.1235C>T p.A412V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100492714; called by muse, mutect2, varscan2
- CCDC73 | c.2036C>A p.S679Y | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as COSV100068555; called by muse, mutect2, varscan2
- CCDC85A | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs554353955, COSV68151378; called by muse, mutect2, varscan2
- CCDC88C | c.1840C>T p.R614W | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as COSV101105147; called by muse, mutect2, varscan2
- CCHCR1 | c.727G>A p.V243M | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV100885964; called by muse, mutect2, varscan2
- CCM2L | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); catalogued as rs778563139, COSV52950492, COSV99395164; called by muse, mutect2, varscan2
- CCNQ | c.433C>A p.L145M | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.974); catalogued as COSV99368102; called by muse, mutect2, varscan2
- CCR5 | c.67dup p.I23Nfs*44 | Frame Shift Ins (INS) | VAF 8/36 reads (22%) | catalogued as rs780235820; called by mutect2, pindel, varscan2
- CD163L1 | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV100550849; called by muse, mutect2, varscan2
- CD177 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.486); catalogued as COSV100946107; called by muse, mutect2, varscan2
- CD79A | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.825); catalogued as rs782657641, COSV99702143; called by muse, mutect2, varscan2
- CD83 | c.473T>C p.L158P | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100997879; called by muse, mutect2, varscan2
- CDC25A | c.832C>T p.R278* | Nonsense Mutation (SNP) | VAF 10/30 reads (33%) | catalogued as COSV56771574; called by muse, mutect2, varscan2
- CDC42BPA | c.2876C>T p.T959M | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.294); catalogued as rs548551223, COSV100507261; called by muse, varscan2
- CDC42BPG | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as rs367615582; called by muse, mutect2, varscan2
- CDC6 | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.033); catalogued as rs767841312, COSV99266725; called by muse, mutect2, varscan2
- CDH24 | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750394497, COSV99944418; called by muse, mutect2, varscan2
- CDR1 | c.57A>G p.I19M | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1274330225, COSV100983472; called by muse, mutect2
- CDR2 | c.322T>C p.S108P | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as COSV99193595; called by muse, mutect2, varscan2
- CDX2 | c.916del p.V306Cfs*2 | Frame Shift Del (DEL) | VAF 9/48 reads (19%) | catalogued as rs773511514; called by mutect2, pindel, varscan2
- CELSR1 | c.5544del p.T1849Rfs*8 | Frame Shift Del (DEL) | VAF 25/89 reads (28%) | catalogued as rs776824429; called by mutect2, pindel, varscan2
- CERKL | c.1273T>C p.F425L (on ENST00000339098 / NM_001030311.2; = p.F399L on NM_201548.5) | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as COSV100184322; called by muse, mutect2, varscan2
- CHAMP1 | c.2164G>T p.G722C | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63522438, COSV63523545; called by muse, mutect2, varscan2
- CHD4 | c.3445C>T p.R1149W (on ENST00000357008 / NM_001363606.2; = p.R1162W on NM_001273.5) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58894467; called by muse, mutect2, varscan2
- CHD7 | c.5494G>A p.E1832K | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); catalogued as rs763196772, COSV101418272, COSV101418614, COSV71108154; called by muse, mutect2, varscan2
- CHD8 | c.4216C>T p.R1406C (on ENST00000646647 / NM_001170629.2; = p.R1127C on NM_020920.4) | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs774260771, COSV100783889; called by muse, mutect2, varscan2
- CHRNA7 | c.1244C>T p.T415M | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.53); catalogued as rs758382061, COSV100181898; called by mutect2, varscan2
- CHST2 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58885684; called by muse, mutect2
- CHST6 | c.442G>A p.V148M | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.671); catalogued as rs766778886, COSV100178696; called by muse, mutect2, varscan2
- CIAO1 | c.474G>A p.W158* | Nonsense Mutation (SNP) | VAF 19/82 reads (23%) | catalogued as rs779741693, COSV99302795; called by muse, mutect2, varscan2
- CIT | c.4847T>C p.L1616P | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99951481; called by muse, mutect2, varscan2
- CLBA1 | c.911T>C p.I304T | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV101121157; called by muse, mutect2, varscan2
- CLDN2 | c.430C>A p.L144I | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.462); catalogued as COSV100390203; called by muse, mutect2, varscan2
- CLIC4 | c.612del p.K204Nfs*11 | Frame Shift Del (DEL) | VAF 9/31 reads (29%) | catalogued as rs1175213607; called by mutect2, pindel, varscan2
- CLSTN2 | c.1840G>A p.V614I | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs764350150, COSV71718527; called by muse, mutect2, varscan2
- CLTC | c.2669C>T p.P890L | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555606635, CM162958, COSV52250313; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- CMYA5 | c.1984T>C p.S662P | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV101484461; called by muse, mutect2
- CNTN4 | c.1319C>T p.T440I | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.297); catalogued as COSV61876826; called by muse, mutect2, varscan2
- COL22A1 | c.4736G>T p.G1579V | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100281393; called by muse, mutect2, varscan2
- COL24A1 | c.2976A>G p.P992= | Splice Region (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100994224; called by mutect2, varscan2
- COL28A1 | c.364A>G p.K122E | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.371); catalogued as COSV101259020; called by muse, mutect2, varscan2
- COL7A1 | c.5171G>A p.R1724H | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.081); catalogued as rs146154014; called by muse, mutect2, varscan2
- CPLANE2 | c.404A>G p.N135S | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs747730146, COSV100983297; called by muse, mutect2, varscan2
- CPT1C | c.2116G>T p.G706C | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99773776; called by muse, mutect2, varscan2
- CR1 | c.3632G>A p.S1211N | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.279); catalogued as COSV100888118; called by muse, mutect2, varscan2
- CRELD2 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1369075955, COSV58207694; called by muse, mutect2, varscan2
- CREM | c.331C>T p.R111C (on ENST00000429130; = p.R62C on NM_001881.3) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs201032782; called by muse, mutect2, varscan2
- CSF3 | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.768); catalogued as rs757845157, COSV99842626; called by muse, mutect2, varscan2
- CSHL1 | c.609G>T p.K203N (on ENST00000309894 / NM_022581.3; = p.K109N on NM_001318.4) | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99368327; called by muse, mutect2, varscan2
- CSMD1 | c.7352C>T p.A2451V (on ENST00000520002; = p.A2450V on NM_033225.6) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as rs541327715, COSV100155408; called by muse, mutect2, varscan2
- CSMD1 | c.2386T>A p.S796T (on ENST00000520002; = p.S795T on NM_033225.6) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.983); catalogued as COSV100154864; called by muse, mutect2, varscan2
- CSMD2 | c.8708G>A p.R2903Q | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.086); catalogued as rs754065561, COSV53888485, COSV99587660; called by mutect2, varscan2
- CSPG4 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV100414318; called by muse, mutect2, varscan2
- CT55 | c.343A>T p.I115F | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV99359009; called by muse, mutect2, varscan2
- CTIF | c.1723G>A p.A575T | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1341860702, COSV99838707; called by muse, mutect2, varscan2
- CTNNA1 | c.1642C>T p.R548W | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1252185833, COSV57072410; called by muse, mutect2, varscan2
- CTRL | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.666); catalogued as rs747823289, COSV99345078; called by muse, mutect2, varscan2
- CUL3 | c.2176-3del | Splice Region (DEL) | VAF 5/30 reads (17%) | catalogued as rs1559333052; called by mutect2, pindel, varscan2
- CYC1 | c.276del p.S93Afs*161 | Frame Shift Del (DEL) | VAF 10/79 reads (13%) | catalogued as rs756254049; called by mutect2, pindel, varscan2
- CYP4B1 | c.1286G>A p.R429H | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs773003953, COSV54722263; called by muse, mutect2, varscan2
- CYP4V2 | c.611C>A p.A204D | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1397867898, COSV101115020; called by muse, mutect2, varscan2
- D2HGDH | c.392dup p.N132Qfs*13 | Frame Shift Ins (INS) | VAF 7/20 reads (35%) | catalogued as rs1158737546; called by mutect2, varscan2
- DAB2IP | c.1795G>A p.E599K (on ENST00000408936; = p.E571K on NM_032552.3) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV52265673; called by muse, mutect2, varscan2
- DACH1 | c.1876C>T p.Q626* (on ENST00000619232 / NM_001366712.1; = p.Q372* on NM_004392.6) | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as COSV100499592; called by muse, mutect2, varscan2
- DBX2 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); catalogued as COSV100224577; called by muse, mutect2, varscan2
- DCBLD1 | c.717G>A p.R239= | Splice Region (SNP) | VAF 16/37 reads (43%) | catalogued as COSV99758305; called by muse, mutect2, varscan2
- DCD | c.125A>C p.K42T | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.025); catalogued as COSV99514157; called by muse, mutect2, varscan2
- DCLRE1C | c.2053del p.R685Efs*6 (on ENST00000378278 / NM_001350965.2; = p.R570Efs*6 on NM_022487.4) | Frame Shift Del (DEL) | VAF 9/31 reads (29%) | catalogued as rs915913541; called by mutect2, pindel, varscan2
- DCST2 | c.905C>T p.S302F | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV99791841; called by muse, mutect2, varscan2
- DDX10 | c.1823C>T p.P608L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs758871651, COSV100489774, COSV100490097; called by muse, mutect2, varscan2
- DDX28 | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.472); catalogued as COSV100193190; called by muse, mutect2
- DENND10 | c.623A>C p.Q208P | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.895); catalogued as COSV100814068; called by muse, mutect2
- DENND5B | c.2041C>T p.Q681* | Nonsense Mutation (SNP) | VAF 9/29 reads (31%) | catalogued as COSV100172460; called by muse, mutect2
- DERL3 | c.121C>A p.L41I | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.536); catalogued as COSV99320405; called by muse, mutect2, varscan2
- DESI1 | c.292G>T p.G98C | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.865); catalogued as COSV99611071; called by muse, mutect2, varscan2
- DGCR2 | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99594148; called by muse, mutect2, varscan2
- DGCR8 | c.1709G>A p.R570Q | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.76); catalogued as rs1173166685, COSV61225545; called by muse, mutect2, varscan2
- DGKQ | c.1832A>C p.K611T | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99298330; called by mutect2, varscan2
- DHFR2 | c.440C>T p.T147M | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as rs367556762; called by muse, mutect2, varscan2
- DHX16 | c.140T>C p.L47P | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99224003; called by muse, mutect2, varscan2
- DHX33 | c.1214G>T p.R405M | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99834193; called by muse, mutect2, varscan2
- DHX33 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as rs1322028888, COSV99834522; called by muse, mutect2, varscan2
- DHX57 | c.1163A>G p.H388R | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0.38); catalogued as rs1377719471, COSV99770098; called by muse, mutect2, varscan2
- DIDO1 | c.2417C>T p.P806L | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781382210, COSV56629390; called by muse, mutect2, varscan2
- DIRAS3 | c.46C>T p.R16W | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1441125525, COSV100921333, COSV63970899; called by muse, mutect2, varscan2
- DISP2 | c.3563G>A p.R1188Q | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs765406694, COSV99140286; called by muse, mutect2, varscan2
- DISP3 | c.2741G>A p.R914Q | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.321); catalogued as rs778638325, COSV99610322; called by muse, mutect2, varscan2
- DKK1 | c.14G>A p.G5D | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.247); catalogued as COSV100906604; called by muse, mutect2
- DLG3 | c.1415G>A p.R472H (on ENST00000374360 / NM_021120.4; = p.R135H on NM_020730.3) | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs747855598, COSV99530245; called by muse, mutect2, varscan2
- DMD | c.2635C>T p.R879W | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV100821430; called by muse, mutect2, varscan2
- DMXL1 | c.7606G>T p.V2536F | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.189); catalogued as COSV100225318; called by muse, mutect2, varscan2
- DNA2 | c.2335del p.S779Hfs*6 | Frame Shift Del (DEL) | VAF 16/57 reads (28%) | catalogued as rs745893364; called by mutect2, varscan2
- DNAAF3 | c.1289T>C p.V430A (on ENST00000524407 / NM_001256715.2; = p.V477A on NM_178837.4) | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV100788054; called by muse, mutect2, varscan2
- DNAH1 | c.2089G>A p.V697M | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.373); catalogued as rs757769710, COSV101327423; called by muse, varscan2
- DNAH1 | c.4132G>A p.E1378K | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs776645685, COSV101326879, COSV101327425; called by muse, mutect2, varscan2
- DNAH1 | c.11152C>T p.R3718C | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs759839153, COSV70228640; called by muse, mutect2, varscan2
- DNAH1 | c.12309G>T p.W4103C | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99964291, COSV99964652; called by muse, mutect2, varscan2
- DNAH17 | c.11140G>A p.V3714I | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.456); catalogued as rs151093068; called by muse, mutect2, varscan2
- DNAH5 | c.5198C>T p.S1733L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs146087064; called by muse, mutect2
- DNAH7 | c.4822G>A p.V1608I | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as COSV100418262; called by muse, mutect2, varscan2
- DNAH7 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100418263; called by muse, mutect2
- DNAH9 | c.571G>T p.G191C | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.052); catalogued as COSV99309040; called by muse, mutect2, varscan2
- DNAH9 | c.4021C>T p.R1341W | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as rs368725644, COSV52381683; called by muse, mutect2, varscan2
- DNAJA2 | c.1085C>T p.P362L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100398966; called by muse, mutect2, varscan2
- DNAJC13 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99607694; called by muse, mutect2, varscan2
- DNM1 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as rs1172228858, COSV57848658, COSV57853940; called by muse, mutect2, varscan2
- DNM1L | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs1217689913, COSV99846569; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DPPA2 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as rs750894184, COSV101524806; called by muse, mutect2, varscan2
- DR1 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); catalogued as COSV100937855; called by muse, mutect2, varscan2
- DRP2 | c.2555G>A p.R852H | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs780817758, COSV101235267; called by muse, mutect2, varscan2
- DSCAM | c.2908G>A p.E970K | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.176); catalogued as rs780067485, COSV68027076; called by muse, mutect2, varscan2
- DSG2 | c.427T>G p.L143V | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as COSV99853676; called by muse, mutect2
- DST | c.18788T>C p.L6263P (on ENST00000361203 / NM_001374722.1; = p.L3960P on NM_015548.5) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99761249; called by muse, mutect2, varscan2
- DTX4 | c.1527del p.G510Afs*35 | Frame Shift Del (DEL) | VAF 13/44 reads (30%) | catalogued as rs762133243; called by mutect2, pindel, varscan2
- DUSP21 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs767788882, COSV100173696; called by muse, mutect2, varscan2
- DUT | c.622A>G p.K208E (on ENST00000331200 / NM_001025248.2; = p.K120E on NM_001948.4) | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as COSV100485352; called by muse, mutect2
- DYNC1H1 | c.9619A>G p.K3207E | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100795635; called by muse, mutect2, varscan2
- DYNC1H1 | c.12290A>C p.K4097T | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV100795636; called by muse, mutect2, varscan2
- DYRK4 | c.1488G>T p.E496D | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV50543634; called by muse, mutect2, varscan2
- ECHS1 | c.121dup p.R41Kfs*5 | Frame Shift Ins (INS) | VAF 28/95 reads (29%) | catalogued as rs751306953; called by mutect2, pindel, varscan2
- EDDM3A | c.171del p.E58Rfs*3 | Frame Shift Del (DEL) | VAF 5/29 reads (17%) | catalogued as rs1243393712; called by mutect2, pindel, varscan2
- EFTUD2 | c.939G>C p.Q313H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV101274567; called by muse, mutect2, varscan2
- EGR2 | c.824del p.G275Afs*6 | Frame Shift Del (DEL) | VAF 20/88 reads (23%) | catalogued as COSV99653876; called by pindel, varscan2
- EIF2D | c.193G>A p.V65M | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.046); catalogued as rs782532326, COSV55113967, COSV99663085; called by muse, mutect2, varscan2
- EIF5A | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as COSV59749160; called by muse, mutect2, varscan2
- EIF5A | c.235A>G p.M79V | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as COSV100223405; called by muse, mutect2, varscan2
- ELAVL3 | c.47del p.G16Afs*35 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | catalogued as rs751148694; called by mutect2, varscan2
- EP300 | c.4879C>T p.R1627W | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV54325405, COSV54343776; called by muse, mutect2, varscan2
- EPAS1 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs148453283; called by muse, mutect2, varscan2
- EPAS1 | c.1648C>T p.R550W | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs771840848, COSV55387675; called by muse, mutect2, varscan2
- EPB41 | c.252_254del p.S85del | In Frame Del (DEL) | VAF 4/21 reads (19%) | catalogued as rs752062682; called by pindel, varscan2
- EPHA1 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV51970732; called by muse, mutect2, varscan2
- EPHX2 | c.1570C>T p.H524Y | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100994857; called by muse, mutect2, varscan2
- EPPK1 | c.6514C>A p.L2172M | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as rs782071803, COSV101599997; called by muse, mutect2, varscan2
- ERBB3 | c.3686C>T p.S1229L | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.373); catalogued as rs1217262342, COSV99918235; called by muse, mutect2, varscan2
- ERCC4 | c.2260C>T p.R754C | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as rs535728795, COSV100318857; called by muse, mutect2, varscan2
- ERLIN1 | c.374A>C p.E125A | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100962363; called by muse, mutect2, varscan2
- ERMAP | c.1369C>A p.L457M | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.219); catalogued as COSV100072456; called by mutect2, varscan2
- ERRFI1 | c.419del p.F140Sfs*35 | Frame Shift Del (DEL) | VAF 18/37 reads (49%) | catalogued as rs34409716; called by mutect2, pindel, varscan2
- ESRP1 | c.1204T>C p.F402L | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV100619768; called by muse, mutect2, varscan2
- EXO5 | c.988C>T p.R330* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as rs772199418, COSV56416773; called by muse, mutect2, varscan2
- F5 | c.3134C>T p.P1045L | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.05); PolyPhen benign (0.035); catalogued as rs751255163, COSV63128282; called by muse, mutect2, varscan2
- F9 | c.724-1G>T p.X242_splice | Splice Site (SNP) | VAF 22/63 reads (35%) | catalogued as CS083921, CS910433, CS941482, COSV54380044; called by muse, mutect2, varscan2
- FAHD2B | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 14/65 reads (22%) | catalogued as rs751966944; called by mutect2, pindel, varscan2
- FAM135B | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.065); catalogued as rs369404911, COSV50523175; called by muse, mutect2, varscan2
- FAM162B | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as rs1468062485, COSV63920285; called by muse, mutect2, varscan2
- FAM3A | c.559G>A p.G187R | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1382546900, COSV100453653; called by muse, mutect2, varscan2
- FAM47B | c.1601C>T p.A534V | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.088); catalogued as COSV61452974; called by muse, mutect2, varscan2
- FAM78A | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs765017509, COSV99908660; called by muse, varscan2
- FAS | c.403del p.C135Vfs*52 | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | catalogued as rs1564692984, CX113055, COSV58238368; called by mutect2, pindel, varscan2
- FASN | c.6594C>T p.S2198= | Splice Region (SNP) | VAF 6/59 reads (10%) | catalogued as rs772045989, COSV60757366; called by mutect2, varscan2
- FBF1 | c.1345C>T p.H449Y (on ENST00000586717; = p.H463Y on NM_001319193.1) | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV100045737; called by muse, mutect2, varscan2
- FBLIM1 | c.577del p.R193Efs*8 | Frame Shift Del (DEL) | VAF 23/79 reads (29%) | catalogued as CM066072; called by mutect2, pindel, varscan2
- FBN3 | c.2126G>A p.C709Y | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV99562114; called by muse, mutect2, varscan2
- FBXO3 | c.1287G>T p.E429D | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated, low confidence (0.58); PolyPhen possibly damaging (0.585); catalogued as COSV55765531, COSV99682400; called by muse, mutect2
- FBXO4 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV99715370; called by muse, mutect2, varscan2
- FCGBP | c.8915G>A p.R2972Q | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.107); catalogued as rs766301042; called by muse, mutect2, varscan2
- FCGBP | c.5203G>A p.V1735I | Missense Mutation (SNP) | VAF 34/250 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs1218328918; called by muse, mutect2, varscan2
- FDXR | c.353C>T p.T118M | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.342); catalogued as rs571288519, COSV99502558; called by muse, mutect2, varscan2
- FGF12 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as COSV53151217; called by muse, mutect2, varscan2
- FHDC1 | c.1991C>T p.S664L | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs768103524, COSV99471882; called by muse, mutect2, varscan2
- FIZ1 | c.115C>T p.R39W | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55607627; called by muse, mutect2, varscan2
- FKBP15 | c.1994del p.K665Rfs*9 | Frame Shift Del (DEL) | VAF 11/53 reads (21%) | catalogued as rs774060142; called by mutect2, pindel, varscan2
- FLNB | c.4604G>A p.S1535N | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as CM061771, COSV99915668; called by muse, mutect2, varscan2
- FLNC | c.2733G>T p.K911N | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.395); catalogued as COSV100369018; called by muse, varscan2
- FLNC | c.6817G>A p.A2273T | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as rs372251350; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLT4 | c.3278C>T p.T1093M | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs770869636, COSV56125072; called by muse, mutect2, varscan2
- FMR1NB | c.164C>A p.P55Q | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as COSV100975651; called by muse, mutect2, varscan2
- FNDC1 | c.4442G>A p.R1481H | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.948); catalogued as rs1275158371, COSV99797460; called by muse, varscan2
- FOLH1 | c.1201A>G p.S401G | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs771545439, COSV99924135; called by muse, mutect2, varscan2
- FOXN1 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 62/170 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as rs760743167, COSV99881622; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FRG2B | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.085); catalogued as rs200937977, COSV101423553; called by muse, mutect2, varscan2
- FRMPD4 | c.1523C>T p.T508M | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs1461743457, COSV66220818; called by muse, mutect2, varscan2
- FSCN3 | c.415del p.R139Dfs*8 | Frame Shift Del (DEL) | VAF 22/64 reads (34%) | catalogued as rs750024016, COSV50002110, COSV99133667; called by mutect2, pindel, varscan2
- FTCD | c.20G>A p.C7Y | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99385656; called by muse, mutect2, varscan2
- FZR1 | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); catalogued as COSV58053257; called by muse, mutect2, varscan2
- G6PC2 | c.122T>A p.I41N | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV99960979; called by muse, mutect2, varscan2
- GABRG3 | c.1393C>A p.L465M | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100405554, COSV61519342; called by muse, mutect2, varscan2
- GAREM1 | c.542T>C p.I181T | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV99331614; called by muse, mutect2, varscan2
- GAS7 | c.1132C>T p.Q378* (on ENST00000432992 / NM_201433.2; = p.Q238* on NM_003644.3) | Nonsense Mutation (SNP) | VAF 18/70 reads (26%) | catalogued as COSV100097428; called by muse, mutect2, varscan2
- GATAD2B | c.1378C>T p.R460W | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV64086824; called by muse, mutect2, varscan2
- GCFC2 | c.2315A>C p.D772A | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as COSV100319775; called by muse, mutect2, varscan2
- GCKR | c.31A>G p.I11V | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.253); catalogued as rs755400366, COSV99254112; called by muse, mutect2, varscan2
- GCN1 | c.2180T>C p.M727T | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100326285; called by muse, mutect2
- GFI1B | c.340A>G p.T114A | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100254576; called by muse, mutect2, varscan2
- GHR | c.1733G>T p.R578M | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.897); catalogued as COSV100052416; called by muse, mutect2, varscan2
- GIT1 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201003587, COSV56613161, COSV99838240; called by muse, mutect2, varscan2
- GJD4 | c.10G>A p.V4M | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.152); catalogued as rs369621128; called by muse, mutect2, varscan2
- GLCE | c.274A>G p.N92D | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99962713; called by muse, mutect2, varscan2
- GLI1 | c.821del p.G274Afs*6 | Frame Shift Del (DEL) | VAF 6/58 reads (10%) | catalogued as rs759448855, COSV99954330; called by mutect2, pindel, varscan2
- GLI2 | c.4591del p.R1531Efs*4 (on ENST00000361492 / NM_001374353.1; = p.R1548Efs*4 on NM_005270.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | catalogued as rs1558946410; called by mutect2, pindel, varscan2
- GLI3 | c.1013C>A p.S338Y | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV101230184; called by muse, mutect2, varscan2
- GLIS1 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.045); catalogued as rs772471069, COSV56547028; called by muse, mutect2, varscan2
- GLS | c.584T>C p.L195P | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100290655; called by muse, mutect2, varscan2
- GLT8D2 | c.331G>A p.V111M | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs367746635; called by muse, mutect2, varscan2
- GLYR1 | c.1140dup p.R381Afs*15 | Frame Shift Ins (INS) | VAF 13/34 reads (38%) | catalogued as rs749150409; called by mutect2, varscan2
- GNA14 | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377352484; called by muse, mutect2, varscan2
- GNAO1 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as CM161438, COSV52615065; called by muse, mutect2, varscan2
- GNAT2 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs776322769, COSV100655959; called by muse, mutect2, varscan2
- GOLGA3 | c.3176C>T p.T1059M | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs753110778, COSV52639660, COSV99213304; called by muse, mutect2, varscan2
- GP5 | c.113del p.G38Afs*9 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as rs750629635; called by mutect2, pindel, varscan2
- GPANK1 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs1224786045, COSV100789063; called by muse, mutect2, varscan2
- GPAT4 | c.62T>A p.V21D | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV101214177; called by muse, mutect2, varscan2
- GPLD1 | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368586631; called by muse, mutect2, varscan2
- GPR149 | c.329T>C p.L110S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV101078854; called by muse, mutect2
- GPR17 | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs554870046, COSV99760569; called by muse, mutect2, varscan2
- GPR19 | c.1109del p.N370Tfs*59 | Frame Shift Del (DEL) | VAF 24/86 reads (28%) | catalogued as rs1416935976; called by mutect2, varscan2
- GPR84 | c.1168C>T p.R390W | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as rs547318808, COSV99910184; called by muse, mutect2, varscan2
- GPRIN2 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs147795605; called by muse, mutect2, varscan2
- GPSM3 | c.396del p.Q133Kfs*8 | Frame Shift Del (DEL) | VAF 9/57 reads (16%) | catalogued as rs752813848; called by mutect2, pindel, varscan2
- GREB1 | c.5366C>T p.A1789V | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as rs369673905, COSV99303719; called by muse, mutect2, varscan2
- GRIK1 | c.812G>T p.R271M | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100518343; called by muse, mutect2, varscan2
- GTF3C1 | c.5541del p.E1848Rfs*33 | Frame Shift Del (DEL) | VAF 18/62 reads (29%) | catalogued as rs763161381; called by mutect2, pindel, varscan2
- GTF3C4 | c.2316-1G>A p.X772_splice | Splice Site (SNP) | VAF 4/21 reads (19%) | catalogued as COSV100936135; called by muse, mutect2, varscan2
- GUCY2C | c.1928del p.K643Rfs*41 | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | catalogued as COSV53786951; called by mutect2, pindel, varscan2
- H2BC14 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as rs1303948079, COSV60798202; called by muse, mutect2, varscan2
- H4C7 | c.71G>A p.S24N | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV99769334; called by muse, mutect2, varscan2
- HAND2 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.657); catalogued as COSV100854162, COSV100854269; called by muse, mutect2, varscan2
- HAPLN1 | c.310dup p.T104Nfs*8 | Frame Shift Ins (INS) | VAF 14/43 reads (33%) | catalogued as rs1561302644; called by mutect2, varscan2
- HDAC6 | c.1649C>T p.A550V | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV100491378; called by muse, mutect2, varscan2
- HDAC9 | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.024); catalogued as rs376682964; called by muse, mutect2, varscan2
- HEATR5A | c.2912G>A p.G971D | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101120760; called by muse, mutect2, varscan2
- HEATR6 | c.416T>C p.I139T | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV99482710; called by muse, mutect2, varscan2
- HECTD3 | c.2416C>T p.P806S | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.988); catalogued as rs1275771703, COSV100938210; called by muse, mutect2, varscan2
- HECW2 | c.4223G>T p.R1408M | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.853); catalogued as COSV99649543; called by muse, mutect2, varscan2
- HELZ | c.3421T>G p.F1141V | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.954); catalogued as COSV100699157; called by muse, mutect2, varscan2
- HERC1 | c.14456del p.P4819Rfs*57 | Frame Shift Del (DEL) | VAF 6/58 reads (10%) | catalogued as COSV71248143; called by mutect2, pindel
- HERC4 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV99517699; called by muse, mutect2, varscan2
- HEXD | c.282+2T>C p.X94_splice | Splice Site (SNP) | VAF 21/66 reads (32%) | catalogued as COSV100028124; called by muse, mutect2, varscan2
- HFM1 | c.3100G>A p.G1034S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54025078; called by muse, mutect2, varscan2
- HGFAC | c.1362del p.R455Gfs*19 | Frame Shift Del (DEL) | VAF 18/52 reads (35%) | catalogued as rs761929917; called by mutect2, pindel, varscan2
- HIPK2 | c.2608C>T p.R870W | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs547460978, COSV100702674; called by muse, mutect2, varscan2
- HMCN1 | c.2575G>A p.A859T | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.99); catalogued as COSV54942544; called by muse, mutect2, varscan2
- HMCN1 | c.14776A>G p.I4926V | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as COSV99637906; called by muse, mutect2, varscan2
- HNF1A | c.832C>T p.R278W | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1344788314, COSV57462558; called by muse, mutect2, varscan2
- HOXA6 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99762545; called by muse, mutect2, varscan2
- HOXB7 | c.535A>G p.R179G | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1338107732, COSV99494249; called by muse, mutect2
- HOXD11 | c.40A>G p.M14V | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as rs1320054791, COSV99983429; called by muse, mutect2, varscan2
- HPD | c.94-2A>G p.X32_splice | Splice Site (SNP) | VAF 12/39 reads (31%) | catalogued as COSV100000274; called by muse, mutect2, varscan2
- HPGD | c.527T>C p.V176A | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99640654; called by muse, mutect2, varscan2
- HPN | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.419); catalogued as rs1290046647, COSV99385420; called by muse, mutect2, varscan2
- HPS1 | c.1382C>T p.P461L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as COSV100282878; called by muse, mutect2, varscan2
- HSD17B2 | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.066); catalogued as rs746830945, COSV99556899; called by muse, mutect2, varscan2
- HSP90AB1 | c.556_558del p.K186del | In Frame Del (DEL) | VAF 17/81 reads (21%) | catalogued as rs760864610; called by pindel, varscan2
- HSPA1B | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100989300; called by muse, mutect2, varscan2
- HSPBAP1 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs373793507; called by muse, mutect2, varscan2
- HSPBAP1 | c.250+1G>A p.X84_splice | Splice Site (SNP) | VAF 8/109 reads (7%) | catalogued as rs1387208136, COSV100063903; called by muse, mutect2
- HTR6 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs200134663, COSV99230558; called by muse, mutect2, varscan2
- HUWE1 | c.11212C>T p.R3738C | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53337071, COSV99474992; called by muse, mutect2, varscan2
- HUWE1 | c.2810T>G p.L937R | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99474999; called by muse, mutect2, varscan2
- IDH3G | c.874G>T p.G292C | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99473511; called by muse, mutect2, varscan2
- IFT122 | c.2659A>G p.K887E (on ENST00000348417 / NM_052989.3; = p.K828E on NM_018262.4) | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.98); catalogued as rs765459017, COSV99960061; called by muse, mutect2, varscan2
- IGF2R | c.451C>T p.H151Y | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs756631085, COSV100808429; called by muse, varscan2
- IGF2R | c.3949dup p.D1317Gfs*5 | Frame Shift Ins (INS) | VAF 13/49 reads (27%) | catalogued as rs760021495; called by mutect2, varscan2
- IGHA1 | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs759216050; called by muse, mutect2, varscan2
- IGSF1 | c.2948T>C p.M983T | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0.061); catalogued as rs1569401438, COSV100812484; called by muse, mutect2
- IKBKB | c.2039G>A p.R680Q | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.012); catalogued as rs140546524, COSV60595829; called by muse, mutect2, varscan2
- IL16 | c.1616T>C p.I539T | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100268381, COSV57261398; called by muse, varscan2
- IL2RA | c.727G>T p.V243L | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.07); catalogued as COSV99907002; called by muse, mutect2, varscan2
- IMPDH1 | c.759G>T p.E253D (on ENST00000470772 / NM_001142573.2; = p.E339D on NM_000883.4) | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV100118848; called by muse, mutect2, varscan2
- INTS12 | c.631C>T p.R211* | Nonsense Mutation (SNP) | VAF 8/44 reads (18%) | catalogued as rs1054087926, COSV100415967, COSV100415970; called by muse, mutect2, varscan2
- IPO9 | c.457G>T p.E153* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | catalogued as COSV100843616; called by muse, mutect2
- IQCA1 | c.2021G>A p.R674Q | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs746688702, COSV99610620; called by muse, mutect2, varscan2
- IQCB1 | c.1513C>T p.Q505* | Nonsense Mutation (SNP) | VAF 12/58 reads (21%) | catalogued as COSV100182211; called by muse, mutect2, varscan2
- IQCG | c.1189G>A p.V397I | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs760266485, COSV54561438; called by muse, varscan2
- IQSEC2 | c.2726A>G p.D909G (on ENST00000642864 / NM_001111125.3; = p.D704G on NM_015075.2) | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as COSV100945150; called by muse, mutect2, varscan2
- IQSEC3 | c.3098C>T p.A1033V (on ENST00000538872 / NM_001170738.2; = p.A730V on NM_015232.1) | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs781803323, COSV100407881; called by muse, mutect2, varscan2
- IRF2 | c.448G>T p.G150* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as COSV101165929; called by muse, mutect2, varscan2
- IRS4 | c.1772del p.G591Afs*20 | Frame Shift Del (DEL) | VAF 12/26 reads (46%) | catalogued as rs780982673; called by mutect2, varscan2
- ITGA9 | c.1270C>T p.R424W | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as rs765270468, COSV53238816; called by muse, mutect2, varscan2
- ITGAD | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs369447868; called by muse, mutect2, varscan2
- ITGAM | c.3199A>G p.I1067V (on ENST00000648685 / NM_001145808.2; = p.I1066V on NM_000632.4) | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763390528, COSV99793371; called by muse, mutect2, varscan2
- ITPRIPL2 | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101198239; called by muse, mutect2, varscan2
- JAK3 | c.2731C>T p.R911C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV71685383; called by mutect2, varscan2
- JMJD1C | c.5651A>G p.E1884G | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV100550930; called by muse, mutect2, varscan2
- JMJD8 | c.393C>T p.D131= | Splice Region (SNP) | VAF 19/68 reads (28%) | catalogued as COSV99556110; called by muse, mutect2, varscan2
- JMJD8 | c.227G>T p.R76M | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.58); catalogued as COSV99556112; called by muse, mutect2, varscan2
- JRKL | c.472A>G p.N158D | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99567643; called by muse, mutect2, varscan2
- KBTBD6 | c.1478G>A p.R493H | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.991); catalogued as rs770974183, COSV65270988, COSV65271193; called by muse, mutect2, varscan2
- KCNB1 | c.464T>C p.L155P | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV100870619, COSV65568123; called by muse, mutect2, varscan2
- KCNJ1 | c.223C>A p.L75I | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV60661552; called by muse, mutect2, varscan2
- KCNJ11 | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775204908, CM152364, COSV100379253; called by muse, mutect2, varscan2
- KDM2A | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101284697; called by muse, mutect2, varscan2
- KDM8 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.329); catalogued as rs201825076, COSV53732280; called by muse, mutect2, varscan2
- KIAA1614 | c.1750C>T p.P584S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.117); catalogued as COSV100851256; called by muse, mutect2, varscan2
- KIF13A | c.3535G>A p.D1179N | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.729); catalogued as rs1196686610, COSV99438993; called by muse, mutect2, varscan2
- KIF19 | c.116A>C p.E39A | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.42); catalogued as COSV100739235; called by muse, mutect2
- KIF26A | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs887527464, COSV59471746; called by muse, mutect2, varscan2
- KIF26A | c.2084G>A p.R695H | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.156); catalogued as rs774219038, COSV59469811, COSV59470835; called by muse, mutect2, varscan2
- KIF26B | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as rs367786764; called by muse, mutect2, varscan2
- KIF5A | c.659C>T p.T220M | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs772697257, COSV99673740; called by muse, mutect2, varscan2
- KLB | c.1469G>A p.R490Q | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs567666148, COSV99962575; called by muse, mutect2, varscan2
- KLF8 | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 10/63 reads (16%) | catalogued as COSV100808498; called by muse, mutect2, varscan2
- KLHL11 | c.1372A>C p.I458L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.451); catalogued as COSV100044543; called by muse, mutect2, varscan2
- KLHL25 | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs138234891; called by muse, mutect2, varscan2
- KLHL36 | c.1430G>A p.R477Q | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.022); catalogued as rs773724735, COSV99257185; called by muse, mutect2, varscan2
- KLHL42 | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs772231994, COSV67145742; called by muse, mutect2, varscan2
- KLHL42 | c.1194del p.C399Vfs*44 | Frame Shift Del (DEL) | VAF 4/19 reads (21%) | catalogued as rs749194179; called by mutect2, pindel, varscan2
- KMT2B | c.5636del p.G1879Vfs*16 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | catalogued as COSV55868319; called by mutect2, pindel, varscan2
- KMT2C | c.3552G>A p.M1184I | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV100078481; called by muse, mutect2, varscan2
- KNDC1 | c.4904G>A p.R1635H | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as rs1298959439, COSV100466644; called by muse, mutect2, varscan2
- KNTC1 | c.2078G>A p.R693Q | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs772245787, COSV100338945; called by muse, mutect2, varscan2
- KRT85 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.772); catalogued as rs781497688, COSV57737852; called by muse, mutect2, varscan2
- KRT9 | c.430G>A p.G144S | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as rs776872326, COSV55853895; called by muse, mutect2, varscan2
- KSR1 | c.872dup p.P292Tfs*22 (on ENST00000644974 / NM_001367810.1; = p.P155Tfs*22 on NM_014238.2) | Frame Shift Ins (INS) | VAF 11/29 reads (38%) | catalogued as rs750491454; called by mutect2, varscan2
- LAMB1 | c.1502G>A p.S501N | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV99741971; called by muse, mutect2, varscan2
- LAMB4 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs1041414973, COSV52733769; called by muse, mutect2, varscan2
- LARGE2 | c.1099G>A p.D367N | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.762); catalogued as rs200777485, COSV57653274; called by muse, mutect2, varscan2
- LARS1 | c.3296G>A p.R1099H (on ENST00000394434 / NM_020117.11; = p.R1072H on NM_016460.3) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs145644461; called by muse, mutect2, varscan2
- LCE3A | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs201031819, COSV59550322; called by muse, mutect2, varscan2
- LETMD1 | c.403G>A p.V135I | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.87); PolyPhen benign (0.007); catalogued as rs976522274, COSV50397393, COSV50398753; called by muse, mutect2, varscan2
- LGI3 | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.538); catalogued as rs1389763550, COSV100103336; called by muse, mutect2, varscan2
- LGR6 | c.431G>A p.R144H (on ENST00000367278 / NM_001017403.1; = p.R92H on NM_021636.3) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1271102676, COSV55167308, COSV99708122; called by muse, mutect2, varscan2
- LHX2 | c.718T>A p.Y240N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.063); catalogued as COSV101010112; called by muse, varscan2
- LHX9 | c.341A>G p.K114R | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.981); catalogued as COSV100436123, COSV61329144; called by muse, mutect2, varscan2
- LLGL2 | c.32C>A p.P11H | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.717); catalogued as COSV99388927; called by muse, mutect2
- LMAN2 | c.881C>A p.P294H | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100288546; called by muse, mutect2, varscan2
- LMTK2 | c.3662G>A p.R1221H | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs150887629, COSV104397615, COSV99808125; called by muse, mutect2, varscan2
- LOXL2 | c.1792C>T p.R598C | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs993296680, COSV66691946; called by muse, mutect2, varscan2
- LRBA | c.1907T>C p.I636T | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100842233; called by mutect2, varscan2
- LRIG2 | c.2549C>T p.A850V | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as COSV100743797; called by muse, mutect2, varscan2
- LRP1B | c.6860G>A p.S2287N | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as COSV101262209; called by muse, mutect2, varscan2
- LRP2 | c.1117T>G p.C373G | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99790872; called by muse, mutect2, varscan2
- LRP2BP | c.643C>T p.L215F | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1197801310, COSV100146089; called by muse, mutect2, varscan2
- LRP6 | c.3755A>G p.Q1252R | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as rs1258349722, COSV99744890; called by mutect2, varscan2
- LRP8 | c.2842G>A p.V948I | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.403); catalogued as rs776502596, COSV100037074; called by muse, mutect2, varscan2
- LRRC24 | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0.416); catalogued as COSV99468437; called by muse, mutect2, varscan2
- LRRN2 | c.1730G>A p.R577Q | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs374611937; called by muse, mutect2, varscan2
- LSS | c.1370C>T p.T457M | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs757016829, COSV62702928; called by muse, varscan2
- LTBP1 | c.1483G>A p.V495I (on ENST00000404816 / NM_206943.4; = p.V169I on NM_000627.4) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.467); catalogued as rs150858532; called by mutect2, varscan2
- MAD1L1 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.22); PolyPhen benign (0.241); catalogued as rs371823704; called by muse, mutect2, varscan2
- MAD2L1BP | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.15); catalogued as COSV100938772; called by muse, mutect2, varscan2
- MAEA | c.388G>T p.V130L | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as COSV99295774; called by muse, mutect2, varscan2
- MAF1 | c.592A>G p.I198V | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.644); catalogued as COSV100075892; called by muse, mutect2, varscan2
- MAGEA12 | c.67C>A p.L23M | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.85); catalogued as COSV100757119; called by muse, mutect2, varscan2
- MAGI1 | c.3320A>G p.Q1107R (on ENST00000402939 / NM_001033057.2; = p.Q1136R on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.026); catalogued as rs1319130386, COSV100443551; called by muse, mutect2, varscan2
- MAMDC4 | c.3626C>T p.P1209L (on ENST00000445819; = p.P1130L on NM_206920.3) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763102822, COSV56375656; called by muse, mutect2, varscan2
- MAN2A2 | c.1582del p.X528_splice | Splice Site (DEL) | VAF 17/80 reads (21%) | catalogued as rs1219552862; called by mutect2, pindel, varscan2
- MAP10 | c.379A>C p.S127R | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as rs781121128, COSV101406578; called by muse, mutect2, varscan2
- MAP1S | c.1426G>A p.V476M | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); catalogued as rs1238439348, COSV100141348; called by muse, mutect2, varscan2
- MAP3K1 | c.1850del p.G617Efs*39 | Frame Shift Del (DEL) | VAF 9/31 reads (29%) | catalogued as CM108514; called by mutect2, pindel, varscan2
- MAP7 | c.1738A>G p.R580G | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as COSV100644069; called by muse, mutect2, varscan2
- MAPK6 | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV99959568; called by muse, mutect2, varscan2
- MAPK8IP3 | c.982G>A p.V328I | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.987); catalogued as rs971746807, COSV99032313; called by muse, mutect2, varscan2
- MAPK8IP3 | c.995T>C p.M332T | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.943); catalogued as rs867666577, COSV99169980; called by muse, mutect2, varscan2
- MARK2 | c.709G>T p.G237* | Nonsense Mutation (SNP) | VAF 34/113 reads (30%) | catalogued as COSV100159281; called by muse, mutect2, varscan2
- MARS2 | c.533C>T p.P178L | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.838); catalogued as COSV99986740; called by muse, mutect2, varscan2
- MAST2 | c.2189C>T p.P730L | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs756675811, COSV63616167; called by muse, mutect2, varscan2
- MBD2 | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1421232155, COSV99840513; called by muse, mutect2, varscan2
- MCM3 | c.2206G>A p.A736T (on ENST00000229854 / NM_001366374.2; = p.A726T on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV57718839; called by muse, mutect2
- MCM3AP | c.1470G>T p.K490N | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as COSV99387660; called by muse, mutect2, varscan2
- MCM4 | c.236-1G>T p.X79_splice | Splice Site (SNP) | VAF 26/96 reads (27%) | catalogued as COSV100031973; called by muse, mutect2, varscan2
- MED1 | c.4148del p.N1383Mfs*26 | Frame Shift Del (DEL) | VAF 5/27 reads (19%) | catalogued as COSV56128694; called by mutect2, pindel, varscan2
- MED1 | c.1709del p.G570Vfs*9 | Frame Shift Del (DEL) | VAF 18/69 reads (26%) | catalogued as COSV56128100; called by mutect2, pindel, varscan2
- MEFV | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.466); catalogued as COSV99561451; called by muse, mutect2, varscan2
- MEGF8 | c.497del p.G166Vfs*53 | Frame Shift Del (DEL) | VAF 24/63 reads (38%) | catalogued as rs762115034; called by mutect2, varscan2
- MESD | c.632del p.K211Rfs*6 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | catalogued as rs745891632; called by mutect2, varscan2
- METTL16 | c.455C>A p.S152Y | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99563914; called by muse, mutect2, varscan2
- METTL3 | c.989A>G p.H330R | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99398735; called by muse, mutect2, varscan2
- MFGE8 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763622380, COSV51555988; called by muse, mutect2, varscan2
- MFSD4A | c.878G>C p.S293T | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.697); catalogued as rs1336299957, COSV100901754; called by muse, mutect2
- MGAM | c.821A>G p.Y274C | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101516587; called by mutect2, varscan2
- MGLL | c.629G>A p.G210D (on ENST00000398104 / NM_001003794.2; = p.G220D on NM_007283.6) | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); catalogued as COSV99412518; called by muse, mutect2, varscan2
- MIA2 | c.176del p.L59Cfs*22 | Frame Shift Del (DEL) | VAF 42/122 reads (34%) | catalogued as rs769553721, COSV54495286; called by mutect2, varscan2
- MIF4GD | c.101T>A p.L34* (on ENST00000325102 / NM_001370592.1; = p.L68* on NM_020679.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 7/52 reads (13%) | catalogued as COSV99821774; called by muse, mutect2, varscan2
- MINK1 | c.2626G>A p.G876R | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.114); catalogued as rs1289473978, COSV99545485; called by muse, mutect2, varscan2
- MLEC | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV57329397, COSV57329841; called by muse, mutect2, varscan2
- MLF1 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as rs200582831, COSV63033841; called by muse, mutect2, varscan2
- MMRN2 | c.1193T>C p.L398P | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100922721; called by muse, mutect2, varscan2
- MORC1 | c.155-1G>A p.X52_splice | Splice Site (SNP) | VAF 7/48 reads (15%) | catalogued as COSV99228282; called by muse, mutect2, varscan2
- MPHOSPH8 | c.2542G>T p.V848F | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100825254; called by muse, mutect2, varscan2
- MR1 | c.412G>A p.G138R | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs749930100, COSV99295171; called by muse, mutect2, varscan2
- MRC2 | c.3542C>T p.T1181M | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.44); catalogued as rs771756598, COSV100316907; called by muse, mutect2, varscan2
- MROH5 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101436208; called by muse, mutect2, varscan2
- MROH7 | c.3599T>C p.L1200P | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100988638; called by muse, mutect2, varscan2
- MRPS9 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1022301070, COSV99306473; called by muse, mutect2, varscan2
- MSH2 | c.2419del p.T807Lfs*5 | Frame Shift Del (DEL) | VAF 8/33 reads (24%) | catalogued as COSV51883854; called by mutect2, pindel, varscan2
- MSH6 | c.3460G>A p.A1154T | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV99317233; called by muse, mutect2, varscan2
- MTCL1 | c.3134G>T p.R1045M (on ENST00000306329 / NM_001378206.1; = p.R726M on NM_015210.4) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100095981; called by muse, mutect2, varscan2
- MTCL1 | c.4181G>A p.R1394H (on ENST00000306329 / NM_001378206.1; = p.R1075H on NM_015210.4) | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs367681723; called by muse, mutect2, varscan2
- MTHFR | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.036); catalogued as rs370713424; called by muse, mutect2, varscan2
- MUC16 | c.27512C>T p.S9171L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs375432429; called by mutect2, varscan2
- MUC16 | c.8201C>T p.A2734V | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as COSV101202326; called by muse, mutect2, varscan2
- MUC5B | c.13034T>C p.V4345A | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs1294225807, COSV101500995; called by muse, mutect2, varscan2
- MUC6 | c.6781G>A p.A2261T | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as rs748267272, COSV70145208; called by muse, mutect2, varscan2
- MYD88 | c.688A>G p.S230G | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100086636; called by muse, mutect2, varscan2
- MYH14 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs745491664, COSV51835225; called by muse, mutect2, varscan2
- MYH7 | c.3446G>A p.R1149Q | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs768978215, COSV100806903; called by muse, mutect2, varscan2
- MYLK | c.1571C>T p.A524V | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100659544; called by muse, mutect2
- MYO10 | c.380G>A p.G127D | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101549946, COSV72454096; called by muse, mutect2, varscan2
- MYO15A | c.8972C>T p.P2991L | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs1345958456, COSV99235018; called by muse, mutect2, varscan2
- MYO9A | c.6340G>T p.D2114Y | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100614696; called by muse, mutect2, varscan2
- MYOD1 | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.142); catalogued as COSV51454354; called by muse, mutect2
- MYOM2 | c.1340T>G p.L447R | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100038785; called by muse, mutect2
- NBEAL2 | c.6517G>A p.V2173M | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as rs768276685, COSV99438120; called by muse, mutect2, varscan2
- NCBP1 | c.2180G>A p.R727Q | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.133); catalogued as rs1275769807, COSV100910675; called by muse, mutect2, varscan2
- NCKAP1 | c.2193G>T p.Q731H | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.072); catalogued as COSV100720632; called by muse, mutect2, varscan2
- NDUFAB1 | c.212T>C p.M71T | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV99141615; called by muse, mutect2
- NECAB2 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100534183; called by muse, varscan2
- NECTIN4 | c.24G>T p.E8D | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.037); catalogued as COSV100920068, COSV63514184; called by muse, mutect2, varscan2
- NELFE | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs754439377, COSV100952920; called by muse, mutect2, varscan2
- NEPRO | c.551+1G>A p.X184_splice | Splice Site (SNP) | VAF 10/26 reads (38%) | catalogued as rs1200778097, COSV100075210; called by muse, mutect2, varscan2
- NEURL4 | c.1613G>A p.R538H | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs369946100; called by muse, mutect2, varscan2
- NFATC1 | c.1767G>T p.Q589H | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99502826; called by muse, mutect2, varscan2
- NFE2 | c.661del p.E221Rfs*13 | Frame Shift Del (DEL) | VAF 15/66 reads (23%) | catalogued as COSV100380730; called by mutect2, pindel, varscan2
- NFKB1 | c.1950C>T p.D650= (on ENST00000394820 / NM_001382627.1; = p.D651= on NM_003998.4 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 10/33 reads (30%) | catalogued as rs771536273, COSV99898055; called by muse, mutect2, varscan2
- NIPSNAP3B | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs557871008, COSV66106573; called by muse, mutect2, varscan2
- NIT1 | c.186G>T p.Q62H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV100919158; called by muse, mutect2, varscan2
- NLRP5 | c.1553G>A p.R518H | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.799); catalogued as rs764760079, COSV66763107; called by muse, mutect2, varscan2
- NLRX1 | c.1222G>A p.G408R | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1216854032, COSV52705765; called by muse, mutect2, varscan2
- NOTCH1 | c.3620G>A p.C1207Y | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99493065; called by muse, mutect2, varscan2
- NOTCH1 | c.968G>C p.C323S | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53109961, COSV99493067; called by muse, mutect2
- NOTCH3 | c.3107G>A p.R1036Q | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs756527298, COSV54647576; called by muse, mutect2, varscan2
- NOTCH3 | c.2834C>T p.S945L | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as rs765975372, COSV54650307; called by muse, mutect2, varscan2
- NPR2 | c.2542C>T p.R848W | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as rs769386938, COSV61043576; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPRL3 | c.1400G>A p.S467N (on ENST00000611875 / NM_001077350.3; = p.S442N on NM_001039476.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/135 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.878); catalogued as rs1328766913, COSV99550165; called by muse, mutect2, varscan2
- NPY4R | c.377C>T p.T126M | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs149694580; called by mutect2, varscan2
- NRAP | c.2453G>A p.S818N (on ENST00000359988 / NM_001322945.2; = p.S783N on NM_006175.4) | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV100748691; called by muse, mutect2, varscan2
- NRXN2 | c.3667G>A p.G1223S | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99636522; called by muse, mutect2, varscan2
- NT5DC2 | c.1009-1G>T p.X337_splice | Splice Site (SNP) | VAF 6/19 reads (32%) | catalogued as COSV58743787; called by muse, mutect2
- NTF3 | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs1327377537, COSV100451139, COSV100451174; called by muse, mutect2, varscan2
- NTSR2 | c.990-1G>A p.X330_splice | Splice Site (SNP) | VAF 4/46 reads (9%) | catalogued as COSV60992063; called by muse, mutect2
- NUFIP1 | c.494del p.K165Rfs*38 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | catalogued as rs770344882; called by mutect2, varscan2
- NUMB | c.1371G>T p.Q457H (on ENST00000355058; = p.Q446H on NM_003744.5) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.401); catalogued as COSV99390642; called by muse, mutect2, varscan2
- NUP107 | c.178C>T p.R60* | Nonsense Mutation (SNP) | VAF 8/27 reads (30%) | catalogued as COSV99971800; called by muse, mutect2, varscan2
- NUP155 | c.3409G>A p.D1137N (on ENST00000231498 / NM_153485.3; = p.D1078N on NM_004298.4) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as rs758413180, COSV99195684; called by muse, mutect2, varscan2
- NUP155 | c.205G>T p.G69* (on ENST00000231498 / NM_153485.3; = p.G10* on NM_004298.4) | Nonsense Mutation (SNP) | VAF 7/33 reads (21%) | catalogued as COSV99195695; called by muse, mutect2, varscan2
- NUP93 | c.152C>T p.T51M | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs573467287, COSV100360611; called by muse, mutect2, varscan2
- NUP93 | c.1703G>A p.R568H | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as rs770548557, COSV100360612; called by muse, mutect2, varscan2
- OBSCN | c.11773G>T p.G3925C | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99486444; called by muse, mutect2, varscan2
- OCA2 | c.2263C>A p.L755M | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV100668915; called by muse, mutect2, varscan2
- OCIAD1 | c.322T>C p.S108P | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99971317; called by muse, mutect2, varscan2
- ODR4 | c.437del p.I147Yfs*33 | Frame Shift Del (DEL) | VAF 18/38 reads (47%) | catalogued as rs1470536319; called by mutect2, pindel, varscan2
- OGDHL | c.2470T>C p.Y824H | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV100934593; called by muse, mutect2, varscan2
- OGFR | c.991G>T p.G331W | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99284649; called by muse, mutect2, varscan2
- ONECUT1 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV59949459; called by muse, mutect2
- OR3A1 | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs376929342; called by muse, mutect2, varscan2
- OR4D5 | c.400C>T p.L134F | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV100189967; called by muse, mutect2, varscan2
- OR5A1 | c.325G>A p.G109S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0.088); catalogued as rs367633461; called by muse, mutect2, varscan2
- OR6A2 | c.640G>T p.G214W | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.993); catalogued as COSV60265940; called by muse, mutect2, varscan2
- OR6C65 | c.181C>T p.L61F | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.714); catalogued as COSV101110223; called by muse, mutect2
- OR8J3 | c.833A>G p.Y278C | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100041111; called by muse, mutect2
- OR9A4 | c.268C>T p.Q90* | Nonsense Mutation (SNP) | VAF 13/58 reads (22%) | catalogued as rs534119605, COSV101516586; called by muse, mutect2, varscan2
- OR9Q1 | c.800C>T p.S267L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs142831243; called by muse, mutect2, varscan2
- ORC3 | c.610del p.R204Gfs*16 | Frame Shift Del (DEL) | VAF 10/84 reads (12%) | catalogued as rs1336736903; called by mutect2, pindel, varscan2
- OTOP3 | c.1633G>A p.G545S | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs201902085, COSV100173150; called by muse, mutect2, varscan2
- P2RX7 | c.1397C>T p.A466V | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs201763761, COSV55857898; called by muse, mutect2, varscan2
- PACRGL | c.4C>T p.Q2* | Nonsense Mutation (SNP) | VAF 14/33 reads (42%) | catalogued as COSV99764427; called by muse, mutect2, varscan2
- PAFAH2 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs764886446, COSV65340265; called by muse, mutect2, varscan2
- PAPPA2 | c.4622G>A p.C1541Y | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV100868406; called by muse, mutect2, varscan2
- PARD3 | c.1366del p.I456* | Frame Shift Del (DEL) | VAF 15/63 reads (24%) | catalogued as rs1484598500; called by mutect2, pindel, varscan2
- PARP2 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV99163126; called by muse, mutect2, varscan2
- PARP6 | c.833G>T p.R278M | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99536493; called by muse, mutect2, varscan2
- PAX7 | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as rs761460050, COSV64751693; called by muse, mutect2, varscan2
- PAXIP1 | c.3193T>C p.S1065P | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101250190; called by muse, mutect2, varscan2
- PC | c.1360G>T p.G454C | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100540935; called by muse, mutect2, varscan2
- PCCA | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV100887096; called by mutect2, varscan2
- PCDH19 | c.587T>C p.L196P | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99721123; called by muse, mutect2, varscan2
- PCDHA11 | c.2089G>A p.V697M | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.284); catalogued as COSV100256090; called by muse, mutect2, varscan2
- PCDHA2 | c.2098C>A p.L700M | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100974209; called by muse, mutect2
- PCDHGA11 | c.2090C>T p.A697V | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV53991735; called by muse, mutect2, varscan2
- PCDHGA5 | c.1939G>A p.E647K | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as rs867970296, COSV53898902; called by muse, mutect2, varscan2
- PCDHGB1 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV99549931; called by muse, mutect2, varscan2
- PCK1 | c.1375G>A p.A459T | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.81); PolyPhen benign (0.071); catalogued as rs766102409, COSV100101106, COSV60127483; called by muse, mutect2, varscan2
- PCMTD1 | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0.02); catalogued as rs767756923, COSV62119286; called by muse, mutect2, varscan2
- PCSK7 | c.545C>T p.T182M | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs150784623; called by muse, mutect2, varscan2
- PDCD7 | c.1085G>A p.R362H | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779453217, COSV99200171; called by muse, mutect2, varscan2
- PDE11A | c.438G>T p.Q146H | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99615963; called by muse, mutect2, varscan2
- PDIA3 | c.686G>A p.S229N | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV100295406; called by muse, mutect2
- PDIK1L | c.636G>T p.K212N | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.407); catalogued as COSV100957737; called by muse, mutect2, varscan2
- PDLIM3 | c.558G>T p.E186D (on ENST00000284770 / NM_001257963.1; = p.E353D on NM_014476.6) | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.204); catalogued as COSV99507963; called by muse, mutect2, varscan2
- PDPR | c.2297G>A p.R766H | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs774452507, COSV55349847; called by muse, mutect2
- PEF1 | c.765G>T p.E255D | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.139); catalogued as COSV101036058; called by muse, mutect2, varscan2
- PER1 | c.2458C>T p.R820* | Nonsense Mutation (SNP) | VAF 12/27 reads (44%) | catalogued as rs1157424943, COSV100424969; called by muse, mutect2, varscan2
- PER1 | c.1138del p.L380Cfs*73 | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | catalogued as rs1196410930; called by mutect2, pindel, varscan2
- PER3 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.092); catalogued as COSV50012673; called by muse, mutect2, varscan2
- PEX3 | c.208C>T p.L70= | Splice Region (SNP) | VAF 23/63 reads (37%) | catalogued as COSV100852272; called by muse, mutect2, varscan2
- PHAX | c.968G>T p.R323M | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV99881739; called by muse, mutect2
- PHC1 | c.2438G>A p.R813H | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764672908, COSV99134353; called by muse, mutect2, varscan2
- PHF3 | c.1598A>T p.D533V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as COSV100014221; called by muse, mutect2, varscan2
- PHF7 | c.919G>T p.D307Y | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV100015637; called by mutect2, varscan2
- PHYH | c.683dup p.V229Sfs*2 | Frame Shift Ins (INS) | VAF 14/68 reads (21%) | catalogued as rs767403321; called by mutect2, pindel, varscan2
- PIGL | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99848628; called by muse, mutect2
- PIGR | c.620T>A p.I207N | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100732692; called by muse, mutect2
- PIK3C2A | c.539C>A p.P180Q | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV99791437; called by muse, mutect2, varscan2
- PIK3R4 | c.3394G>A p.A1132T | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.788); catalogued as COSV100768657; called by mutect2, varscan2
- PIP4P2 | c.175C>A p.R59S | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV53438552, COSV99575665; called by muse, mutect2, varscan2
- PIP5K1B | c.148C>T p.R50* | Nonsense Mutation (SNP) | VAF 14/54 reads (26%) | catalogued as rs1183270881, COSV99600114; called by muse, varscan2
- PIP5K1C | c.1979del p.P660Rfs*225 | Frame Shift Del (DEL) | VAF 8/16 reads (50%) | catalogued as rs748532409; called by mutect2, varscan2
- PKD2 | c.2587G>A p.V863M | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs766821096, COSV52939396, COSV99417949; called by mutect2, varscan2
- PKDREJ | c.2012C>T p.T671I | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.852); catalogued as COSV53554646; called by muse, mutect2
- PKDREJ | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.197); catalogued as COSV53549911; called by muse, mutect2, varscan2
- PLCB2 | c.2032G>A p.V678M | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.731); catalogued as rs755412316, COSV53035476; called by muse, mutect2, varscan2
- PLD2 | c.2609G>A p.R870H | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as rs201356383, COSV54010419; called by muse, mutect2, varscan2
- PLEKHA4 | c.1571T>C p.L524P | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as COSV99613502; called by muse, mutect2, varscan2
- PLEKHA5 | c.2263C>T p.R755C | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs770413546, COSV54704705; called by muse, mutect2, varscan2
- PLEKHG3 | c.520C>T p.R174C (on ENST00000394691; = p.R230C on NM_001308147.2) | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767305583, COSV55985115; called by muse, mutect2, varscan2
- PLEKHM2 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as rs764949831, COSV101009236; called by muse, mutect2, varscan2
- PLPPR2 | c.764G>A p.R255H | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759194929, COSV52261960, COSV99264840; called by muse, mutect2, varscan2
- PLXNB1 | c.6160G>A p.A2054T | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as COSV99603656; called by muse, mutect2
- PLXNB3 | c.4360C>T p.L1454F | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100738083; called by muse, mutect2, varscan2
- PLXND1 | c.4417G>A p.A1473T | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.857); catalogued as rs759179980, COSV100139242; called by muse, mutect2, varscan2
- PM20D1 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV65649285; called by muse, mutect2, varscan2
- PNKD | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs777574834, COSV51231307, COSV99282122; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PNKP | c.1127-1G>A p.X376_splice | Splice Site (SNP) | VAF 18/41 reads (44%) | catalogued as rs903931173, COSV55589654; called by muse, mutect2, varscan2
- PNMA8B | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.827); catalogued as COSV66537275; called by muse, mutect2, varscan2
- PNPLA6 | c.3325T>C p.Y1109H (on ENST00000414982 / NM_001166111.2; = p.Y1061H on NM_006702.5) | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99654750; called by muse, mutect2
- POLA1 | c.3584C>A p.P1195H | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV100985886; called by muse, mutect2, varscan2
- POLD1 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs755457889, COSV101486745; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLL | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs376114934, COSV54576311; called by muse, mutect2, varscan2
- POLR1A | c.4603A>G p.K1535E | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.334); catalogued as COSV99808650; called by muse, mutect2, varscan2
- POLR2F | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as rs35083758; called by muse, varscan2
- POLR2K | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs758836631, COSV52560224, COSV99073994; called by muse, mutect2, varscan2
- POSTN | c.1659A>G p.I553M | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV101123547; called by muse, mutect2, varscan2
- POT1 | c.1598T>A p.L533Q | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100714169; called by muse, mutect2
- PPARGC1A | c.1084T>C p.S362P | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.477); catalogued as COSV99338938; called by muse, mutect2, varscan2
- PPME1 | c.1074G>T p.K358N | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV100076824; called by muse, mutect2, varscan2
- PPP1R7 | c.166dup p.E56Gfs*9 | Frame Shift Ins (INS) | VAF 6/30 reads (20%) | catalogued as rs755881645; called by mutect2, pindel, varscan2
- PPP6R3 | c.1744C>T p.R582* (on ENST00000393800 / NM_001352375.2; = p.R502* on NM_018312.5) | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as COSV99677904; called by muse, mutect2, varscan2
- PRAM1 | c.1792G>A p.A598T | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs760422876, COSV55311797; called by muse, mutect2, varscan2
- PRDM15 | c.1273C>T p.R425C | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs199833702, COSV99063604; called by muse, mutect2, varscan2
- PRDX4 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV101026788; called by muse, mutect2, varscan2
- PREX1 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746332373, COSV64247740; called by muse, mutect2, varscan2
- PRKCE | c.341A>G p.E114G | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV100079908; called by muse, mutect2, varscan2
- PRKCG | c.1372G>A p.A458T | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.026); catalogued as COSV99669738; called by muse, mutect2, varscan2
- PRKN | c.709A>G p.T237A | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV58241167; called by muse, mutect2, varscan2
- PRKX | c.248C>A p.P83H | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.962); catalogued as COSV99468826; called by muse, mutect2, varscan2
- PRPF8 | c.5621T>C p.V1874A | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.62); catalogued as COSV100518058; called by muse, mutect2, varscan2
- PRR11 | c.66del p.E23Kfs*9 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | catalogued as rs753236928; called by mutect2, varscan2
- PRR14 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as rs780562158, COSV99788333; called by muse, mutect2, varscan2
- PRR22 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1184660156, COSV100288572; called by muse, mutect2
- PRR5L | c.10G>A p.G4S | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.627); catalogued as rs777175298, COSV100287457; called by muse, mutect2, varscan2
- PRRT1 | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.913); catalogued as COSV99278745; called by muse, mutect2, varscan2
- PRSS23 | c.1021dup p.S341Ffs*34 | Frame Shift Ins (INS) | VAF 5/16 reads (31%) | catalogued as rs1565351247; called by mutect2, pindel, varscan2
- PSD4 | c.1918C>T p.R640W | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99831579; called by muse, mutect2, varscan2
- PSMC6 | c.524G>A p.R175H (on ENST00000612399; = p.R161H on NM_002806.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as rs1400222509, COSV101471188, COSV101471220; called by muse, mutect2, varscan2
- PTCH2 | c.403C>T p.H135Y | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100942307; called by muse, mutect2, varscan2
- PTCHD4 | c.2472G>T p.K824N | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.987); catalogued as COSV100262039; called by muse, mutect2, varscan2
- PTPN21 | c.1733C>T p.T578M | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100162690; called by muse, mutect2, varscan2
- PTPRC | c.1888G>A p.V630M | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as rs1455154652, COSV100723354; called by muse, mutect2, varscan2
- PTTG1 | c.491del p.P164Lfs*4 | Frame Shift Del (DEL) | VAF 14/62 reads (23%) | catalogued as rs1042131472; called by mutect2, pindel, varscan2
- PWP2 | c.1541C>T p.S514F | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99380341; called by mutect2, varscan2
- PYDC1 | c.56A>C p.E19A | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100265498; called by muse, mutect2, varscan2
- PYGL | c.2125C>A p.L709M | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.059); catalogued as COSV99369236; called by muse, mutect2
- PYGL | c.1726C>T p.R576* | Nonsense Mutation (SNP) | VAF 18/52 reads (35%) | catalogued as rs774646420, COSV53583928; called by muse, mutect2, varscan2
- QSOX2 | c.1603C>A p.L535I | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.896); catalogued as COSV100699910; called by muse, mutect2, varscan2
- RAB13 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.44); catalogued as rs145912655; called by muse, mutect2, varscan2
- RAB36 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as rs765726662, COSV99321292; called by muse, mutect2, varscan2
- RACGAP1 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs765257119, COSV100408027; called by muse, mutect2, varscan2
- RACK1 | c.118A>G p.I40V | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs893916495, COSV65175820; called by muse, mutect2, varscan2
- RAD23A | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs765282021, COSV100331215; called by muse, mutect2, varscan2
- RAD52 | c.468-2A>G p.X156_splice | Splice Site (SNP) | VAF 19/62 reads (31%) | catalogued as COSV99942760; called by muse, mutect2, varscan2
- RAD9A | c.778T>C p.F260L | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.057); catalogued as COSV100335112; called by muse, mutect2, varscan2
- RAG2 | c.1496del p.K499Sfs*4 | Frame Shift Del (DEL) | VAF 35/124 reads (28%) | catalogued as rs1251406873; called by mutect2, pindel, varscan2
- RANBP3 | c.1421G>A p.R474H (on ENST00000340578 / NM_007322.3; = p.R469H on NM_003624.3) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs376615281; called by muse, mutect2, varscan2
- RAP1GAP2 | c.1688G>A p.R563H | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as rs750434688, COSV54574764, COSV99624768; called by muse, mutect2, varscan2
- RASGEF1B | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs527942666, COSV52337428; called by muse, mutect2, varscan2
- RASGRF1 | c.2294C>G p.T765S | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.99); catalogued as COSV101174872; called by muse, mutect2
- RASSF9 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs369587129; called by mutect2, varscan2
- RBAK-RBAKDN | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV101208267; called by muse, mutect2, varscan2
- RBM26 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs1307109321, COSV99936756; called by muse, mutect2, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 11/36 reads (31%) | catalogued as rs762006287; called by mutect2, varscan2
- RBM39 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as rs1288750952, COSV53614574; called by muse, mutect2, varscan2
- RECQL5 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs762104670, COSV99503110; called by muse, mutect2, varscan2
- REG3G | c.262G>A p.V88M | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as rs779615598, COSV55449323, COSV55450779; called by mutect2, varscan2
- RELCH | c.3017C>T p.P1006L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764754428, COSV56884223; called by muse, mutect2, varscan2
- RETREG2 | c.1087G>T p.G363* | Nonsense Mutation (SNP) | VAF 6/33 reads (18%) | catalogued as COSV99811767; called by muse, mutect2, varscan2
- RETSAT | c.1256C>T p.A419V | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.034); catalogued as rs750768086, COSV99806129; called by muse, mutect2, varscan2
- REV1 | c.1624G>A p.D542N | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.975); catalogued as rs776667456, COSV99301684; called by muse, mutect2, varscan2
- RGL2 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.984); catalogued as rs775361897, COSV101442503; called by muse, mutect2, varscan2
- RGS9 | c.1849G>A p.V617M | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs370867384; called by muse, mutect2, varscan2
- RHBDD2 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.029); catalogued as rs928236647, COSV50086731; called by muse, mutect2, varscan2
- RHBDL2 | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201194443, COSV56709484; called by muse, mutect2, varscan2
- RHCG | c.437T>G p.V146G | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV99174376; called by muse, mutect2
- RIMBP2 | c.1463C>G p.A488G | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV99900960; called by muse, mutect2
- RIPK3 | c.715C>T p.R239W | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as rs373898638; called by muse, mutect2, varscan2
- RMC1 | c.1145A>G p.Q382R | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV99340527; called by muse, mutect2
- RNF10 | c.2338G>A p.A780T | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV58048858; called by muse, mutect2, varscan2
- RNF121 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 49/197 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.483); catalogued as COSV100683760; called by muse, mutect2, varscan2
- RNF123 | c.2779G>A p.A927T | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1278718078, COSV100246801; called by muse, mutect2, varscan2
- RNF20 | c.1535G>A p.R512H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs1351915357, COSV66661581; called by muse, mutect2
- RNF216 | c.2086G>T p.G696C (on ENST00000425013 / NM_207116.3; = p.G753C on NM_207111.4) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101111410; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 16/66 reads (24%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNF6 | c.352C>T p.R118W | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs371597920; called by muse, mutect2, varscan2
- RNPEP | c.871A>G p.M291V | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs1291308199, COSV99821960; called by muse, mutect2, varscan2
- ROBO1 | c.3184C>T p.R1062C | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.786); catalogued as rs759596661, COSV71398331; called by muse, mutect2, varscan2
- RORA | c.385C>T p.R129* (on ENST00000335670 / NM_134261.3; = p.R154* on NM_002943.3) | Nonsense Mutation (SNP) | VAF 8/68 reads (12%) | catalogued as COSV99832575; called by muse, mutect2, varscan2
- RPL10L | c.189A>C p.E63D | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.163); catalogued as COSV100022848; called by muse, mutect2, varscan2
- RPP38 | c.593C>A p.P198H | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100975703; called by muse, mutect2, varscan2
- RPS25 | c.134A>T p.N45I | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100548966; called by muse, mutect2, varscan2
- RPS6KB2 | c.801G>A p.P267= | Splice Region (SNP) | VAF 27/74 reads (36%) | catalogued as rs1229374921, COSV57051821; called by muse, mutect2, varscan2
- RPS6KC1 | c.110T>C p.V37A | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.371); catalogued as COSV100874154; called by muse, mutect2, varscan2
- RPUSD1 | c.445G>A p.V149M | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.035); catalogued as rs754419281, COSV99136053; called by muse, mutect2, varscan2
788 further variants in this file (419 protein-altering or splice-affecting, 336 silent, 33 other) are not listed here.
